CCDI case PBBXVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/09e0bec6-c209-4ef0-b28a-e0c99fbdce7b

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 16.5 years (6,028 days).

Biospecimens (3 samples)
- Sample 0DKAKL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKAKW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DKAMR: Tissue type: Tumor; Specimen type: Solid Tissue.
